Gene-level copy-number profile of tumor specimen TCGA-CG-5718-01A from TCGA case TCGA-CG-5718, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 78.7 years (28,763 days).
Specimen TCGA-CG-5718-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.127c0dd2-74cb-4fe8-a049-a9afec154d9d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-5718-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/39fdebbd-cc19-4d3e-8fc1-b3b62b44424b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 9,720; copy number 2: 33,524; copy number 3: 11,771; copy number 4: 1,106; copy number 5: 2,173; copy number 6: 1,025; copy number 7: 245; copy number 8: 20; copy number 10: 79; copy number 13: 84; copy number 17: 50; copy number 31: 1; copy number 47: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-5718-01A-11D-1599-01): tumor purity 0.58, ploidy 2.28, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:50,968,019–51,845,628, 11 genes (within-gene range 0–2): AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,680 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:34,134,371–34,220,575, 1 gene, copy number 5: AC008170.1.
- chr2:105,874,509–111,120,610, 115 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:129,242,173–138,975,006, 227 genes, copy number 5–8 (broad region; genes not listed).
- chr2:166,403,573–166,611,482, 1 gene, copy number 6 (within-gene range 4–6): SCN7A.
- chr2:166,888,480–167,941,180, 8 genes, copy number 6: XIRP2, AC092601.1, XIRP2-AS1, AC073050.1, RNU7-148P, CTAGE14P, B3GALT1-AS1, B3GALT1.
- chr2:172,137,345–185,957,063, 227 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–7 (broad region; genes not listed).
- chr6:37,091,314–48,111,078, 255 genes, copy number 5–13 (broad region; genes not listed).
- chr7:117,560,733–117,883,675, 5 genes, copy number 6: CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1.
- chr8:46,028,804–96,160,806, 759 genes, copy number 5–7 (broad region; genes not listed).
- chr8:98,189,826–145,066,685, 744 genes, copy number 5–7 (broad region; genes not listed).
- chr10:121,478,332–127,452,517, 106 genes, copy number 13–47 (within-gene range 1–47) (broad region; genes not listed).
- chr13:43,543,918–43,629,464, 2 genes, copy number 6: ENOX1-AS1, AL161714.1.
- chr14:18,333,726–20,679,512, 134 genes, copy number 5 (broad region; genes not listed).
- chr17:142,789–2,511,891, 99 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:9,250,471–9,805,100, 13 genes, copy number 6 (within-gene range 1–6): STX8, AC005695.2, AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1, AC027045.2, DHRS7C.
- chr18:35,366,694–37,762,131, 39 genes, copy number 5–7 (within-gene range 3–7): ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2, KIAA1328, AC016493.1, AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40.
- chr20:50,162,765–62,603,355, 235 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,413. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
